Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A1CA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A1CA-01A (Primary Tumor).

[page 1 of 5]
Adenocarcinoma, serous, NOS 8441/3
Site Code: Endometrium C54.1

1/9/11 *lev*

Surg Path Final Report

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Diagnosis:

**1) UTERUS, CERVIX, AND BILATERAL ADNEXA
ENDOMETRIUM -**

- SEROUS ADENOCARCINOMA WITH SUPERFICIAL MYOMETRIAL INVASION AND WITHOUT NODAL METASTASES; pT1b, pNO, pMx

CERVIX -

- SEROUS ADENOCARCINOMA EXTENDING INTO THE CERVICAL STROMA

MYOMETRIUM -

- ADENOMYOSIS

- LEIOMYOMATA

UTERINE SEROSA AND CUL-DE-SAC -

- NO EVIDENCE OF MALIGNANCY

2) LYMPH NODES, RIGHT PELVIC

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES

3) LYMPH NODES, LEFT PELVIC

- NO EVIDENCE OF MALIGNANCY IN SIX LYMPH NODES

4) LYMPH NODES, RIGHT PERIAORTIC

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES

5) LYMPH NODES, LEFT PERIAORTIC

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES

6) APPENDIX, INCIDENTAL APPENDECTOMY

- BENIGN APPENDIX

(Electronically signed by)

N/A

Name:

MRN:

Acct#:

Client ID:

Age:

Loc:

DOB:

Sex: Female

[page 2 of 5]
Surg Path Final Report

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Diagnosis:

1) UTERUS, CERVIX, AND BILATERAL ADNEXA

ENDOMETRIUM -

- SEROUS ADENOCARCINOMA WITH SUPERFICIAL MYOMETRIAL INVASION AND WITHOUT NODAL METASTASES; pT1b, pN0, pMx

CERVIX -

- SEROUS ADENOCARCINOMA EXTENDING INTO THE CERVICAL STROMA

MYOMETRIUM -

- ADENOMYOSIS

- LEIOMYOMATA

UTERINE SEROSA AND CUL-DE-SAC -

- NO EVIDENCE OF MALIGNANCY

2) LYMPH NODES, RIGHT PELVIC

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES

3) LYMPH NODES, LEFT PELVIC

- NO EVIDENCE OF MALIGNANCY IN SIX LYMPH NODES

4) LYMPH NODES, RIGHT PERIAORTIC

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES

5) LYMPH NODES, LEFT PERIAORTIC

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES

6) APPENDIX, INCIDENTAL APPENDECTOMY

- BENIGN APPENDIX

Verified:

N/A

Name:

MRN:

Acct#:

Client ID:

Age
Loc.

DOB:

Sex: Female

[page 3 of 5]
Surg Path Final Report

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

CAP Protocol:

I: Endometrium, Hysterectomy, Macroscopic

SPECIMEN TYPE:

Radical hysterectomy (includes parametria)

*TUMOR SITE:

*Specify location(s), if known: Endometrium

TUMOR SIZE:

Greatest dimension: 6 cm

*Additional dimensions: 2.5 x 1.5 cm

OTHER ORGANS PRESENT:

Right ovary

Left ovary

Right fallopian tube

Left fallopian tube

I: Endometrium, Hysterectomy, Microscopic

HISTOLOGIC TYPE:

Scrous adenocarcinoma

HISTOLOGIC GRADE:

Not applicable

MYOMETRIAL INVASION:

Invasion present

Specify depth of invasion: 6 mm

Specify myometrial thickness: 20 mm

PRIMARY TUMOR (pT):

pT1b (IB): Tumor confined to corpus uteri: Tumor invades less than one-half of the myometrium

REGIONAL LYMPH NODES (pN):

pN0: No regional lymph node metastasis

Number examined: 14

Number involved 0

DISTANT METASTASIS (pM):

pMX: Cannot be assessed

MARGINS:

Uninvolved by invasive carcinoma

*Distance of invasive carcinoma from closest margin: 5 mm

*Specify margin: Cervical/vaginal

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

*Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*None identified

Specimen(s):

1. UTERUS, TUBES, OVARIES AND OMENTUM
2. RIGHT PELVIC LYMPH NODE
3. LEFT PELVIC LYMPH NODE
4. RIGHT PERIAORTIC LYMPH NODE
5. LEFT PERIAORTIC LYMPH NODE
6. APPENDIX

N/A

Name:

MRN:

Acct#:

Client ID:

Age:

DOB:

Loc:

Sex: Female

[page 4 of 5]
Surg Path Final Report

Accession Number

Collected Date/Time

Received Date/Time

Pathologist

Clinical Information:

Uterine cancer.

Frozen Section Diagnosis:

1) UTERUS, TUBES, OVARIES AND OMENTUM

- Adenocarcinoma (serous)
- Excision Therapeutics obtained

Gross Description:

1) Specimen 1 designated as "uterus, tubes, ovaries and omentum" is received fresh in a container labeled with the patient's name and medical record number and consists of a uterus with cervix attached and bilateral adnexa attached which weighs 433 grams. The uterus and cervix together measure 13 x 8 x 8 cm. The serosal surface is smooth and glistening and the cervical portio is smooth and tan with an external os and measures 1.0 cm in width. The uterus and cervix is opened to reveal an irregular shaped light tan mass that completely covers the surface of the endometrium and extends up the endocervical canal almost to the internal os. This is both on the posterior and anterior. The posterior measurement is approximately 9.7 x 5.5 and the anterior measurement is 8.0 x 5.5 cm. A large submucosal light tan mass is also present which measures 7 x 7 cm. Frozen section is done by _____ and submitted in FS1A. The right fallopian tube measures 2.0 x 0.5 cm. The adjacent ovary measures 1.7 x 1.0 x 1.8 cm. Additional sections are submitted as:

- 1B & C: Right parametrial and paracervical tissue
- 1D & E: Left parametrial and paracervical tissue
- 1F: Anterior transformation zone and endocervical canal
- 1G: Posterior transformation zone and endocervical canal
- 1H: Section through the neck of the cervix for cancer studies
- 1I & J: Tumor and anterior endomyometrium
- 1K & L: Tumor and posterior endomyometrium
- 1M: Right fallopian tube and ovary
- 1N: Left fallopian tube and ovary
- 1O & P: Omentum
- 1Q: Submucosal light tan mass
- 1R: Section of normal appearing ovary for cancer studies

2) Specimen 2 designated as "right pelvic nodes" is received in formalin in a container labeled with the patient's name and medical record number and consists of multiple irregular shaped fragments of yellow adipose tissue which have an aggregate measurement of 6 x 5 x 2.3 cm. Several lymph nodes are appreciated which range from 0.3 to 1.5 cm in greatest dimension. Sections are submitted as:

- 2A-2B: Lymph nodes
- 2C: One bisected node
- 2D: One bisected node

3) Specimen 3 designated as "left pelvic nodes" is received in formalin in a container labeled with the patient's name and medical record number and consists of multiple irregular shaped fragments of yellow adipose tissue which have an aggregate measurement of 6.3 x 4.6 x 2.0 cm. Several lymph nodes are appreciated which range from 0.5 to 3.0 cm in greatest dimension. Sections are submitted as:

- 3A: Lymph nodes
- 3B: One bisected node
- 3C: One bisected node
- 3D: One bisected node

N/A

Name:

MRN:

Acct#:

Client ID:

Age

Loc:

J:

Sex: Female

[page 5 of 5]
IRPAA Discrepancy		
First Malignancy History		

Surg Path Final Report

Accession Number	Collected Date/Time	Received Date/Time	Pathologist
------------------	---------------------	--------------------	-------------

4) Specimen 4 designated as "right paraortic nodes" is received in formalin in a container labeled with the patient's name and medical record number and consists of two irregular shaped fragments of yellow adipose tissue which have an aggregate measurement of 3.5 x 2.5 x 1.3 cm. Two possible lymph nodes are appreciated which range from 0.5 to 2.2 cm in greatest dimension. Sections are submitted as:

- 4A: One bisected node
4B: One possible lymph node

5) Specimen 5 designated as "left paraortic nodes" is received in formalin in a container labeled with the patient's name and medical record number and consists of two possible lymph nodes which range from 0.8 to 0.9 cm in greatest dimension. Sections are submitted in toto in cassette 5A.

6) Specimen 6 designated as "appendix" is received in formalin in a container labeled with the patient's name and medical record number and consists of a vermiform appendix with attached adipose tissue which measures 7.8 x 0.6 cm. The serosal surface is smooth and glistening. The lumen is devoid of substance. The proximal section is notched and representative sections from the proximal, distal and middle of the appendix are submitted in cassette 6A.

Microscopic Description:

A microscopic exam was performed.

Intradepartmental Consultation:

N/A

Name:

MRN:

Acc#: _____

Client ID: _____

Age: _____

Loc: _____

Sex: Female

Source: NCI Genomic Data Commons file 4e2413f3-d23a-4ebf-96e3-8c0c21fdd16e (TCGA-AX-A1CA.5906346F-CB34-421F-BBC3-3B6D2239AA7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).